Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QC, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QC-01C (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Surgical Pathology Report

PATIENT:
ACCOUNT#:
DOB:
AGE: **SEX:** F
ATTENDING:
REQUESTING:
CONTACT NO: (MD)
COPIES TO:

MRN:
RECEIVED DATE:
PROCEDURE DATE:
SIGN-OUT DATE:
LOCATION:
ROOM:

DIAGNOSIS:

1. Lymph node, paraaortic (excision): Reactive lymph node. No tumor seen.
2. Kidney, left base "mass" (excision): Necrotic debris.
3. Kidney, left, deeper base "mass" (excision): Kidney parenchyma. No tumor seen.
4. Kidney and adrenal, left, morcellated (nephrectomy-morcellated): Renal cell carcinoma, chromophobe type, Fuhrman nuclear grade II with extensive necrosis and acute and chronic inflammation. Diffuse interstitial nephritis. Vascular and ureteral margins free of tumor. Focal ureteritis. No capsular invasion seen. Adrenal gland. No tumor seen.

IED-0-3
Carcinoma, renal cell
Chromophobe type 8817/3
Site @ Kidney NOS C64.9
9/24/13

NOTE:

Kidney Nephrectomy Summary Table Macroscopic

Specimen Type: Nephrectomy - morcellated
Laterality: Left
Tumor Size: 4 cm
Focality: Unifocal

Macro Extent of Tumor: Confined to kidney

Microscopic

Histologic Type: Renal cell carcinoma, chromophobe type,
Histologic Grade: Fuhrman nuclear grade II

Patient Identification

[page 2 of 3]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name:

MRN:

Date of Report:

Extent of Invasion

Primary Tumor(pT): pT1a

Regional Lymph Nodes(pN): pN0

Distant Metastasis(pM): pMx

Margins: Vascular, ureteral and inked surgical margins free of tumor

CLINICAL INFORMATION: Brief Clinical History: female wiht left renal mass
Specimen Taken For Protocol: Allocate Order to Protocol:

PROCEDURE: Operative Findings: left upper pole mass Post-Operative Diagnosis: left renal mass
Pre-Operative Diagnosis: left renal mass

SPECIMENS SUBMITTED: 1. ROUTINE + 6FS, Peri-aortic lymph node (1FS)
2. SERIAL 5 + 6FS, Left kidney mass (2FS)
3. ROUTINE + 3FS, Left kidney mass (3FS)
4. KIDNEY, Left adrenal morgellated

INTRAOPERATIVE CONSULTATION:

1. 1FS Diagnosis: Lymph nodes, no definitive tumor seen on frozen section.

The Frozen Sections were performed by

2FS Diagnosis: Fragments of probable epithelioid tumor cells with coagulative necrosis; definitive characterization deferred to permanent.

3FS Diagnosis: Portion of renal cortical tissue with focal mild interstitial inflammation, no definitive tumor seen on frozen sections.

The Frozen Sections were performed by

GROSS DESCRIPT Received are 4 formalin-filled containers labeled with the patient's name, medical record number, and further described as follows:

1. "Paraaortic lymph node". The specimen is a tan to red/brown soft tissue fragment measuring 1.6 x 1.2 x 0.2 cm. The specimen is frozen in toto as 1FS. In Surgical Pathology, the specimen is entirely transferred into an orange cassette labeled for permanent processing.

Patient Identification

[page 3 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name

MRN:

Date of Report:

2. "Left kidney mass base". The specimen is multiple (3) tan tissue fragments measuring 0.2 x 0.2 x 0.1 cm in aggregate. The specimen is frozen in toto. In Surgical Pathology, the specimen is transferred into an orange cassette labeled for permanent processing.

3. "Left kidney mass deeper base". The specimen is a piece of red/brown tissue measuring 1.0 x 0.5 x 0.4 cm. The specimen is frozen in toto as 3FS. In Surgical Pathology, the specimen is entirely transferred to an orange cassette labeled for permanent processing.

4. "Kidney and adrenal – morcellated" Received is a specimen labeled "left kidney and adrenal morcellated". The specimen consists of a simple nephrectomy specimen three pieces measuring 16 x 10 x 5 cm in aggregate. The adrenal gland is identified. The ureteral and vascular structures are identified by surgical staples. The specimen is inked black and bisected revealing a 4 cm diameter tumor mass with a tan-yellow, soft, necrotic cut surface. 50% of the tumor is procured for . Representative normal is procured for Research. Procurement was performed by on to The vascular/ureteral margins are submitted in white cassettes 4A-C. The most distal end of the ureter is submitted in white cassette : 4D. Sections of the most inferior aspect of the tumor and kidney, inferior aspect of the tumor (most adjacent to the kidney) are submitted in white cassettes A section of adrenal gland is submitted in 4G. Representative sections of fat are submitted in 4H. A representative section of normal kidney renal parenchyma is submitted in 4I. Representative sections of the tumor are also submitted in 4J-4Q for permanent processing.

Gross dictated by

No consultants

Patient Identification

Source: NCI Genomic Data Commons file 946e8a27-8a40-4f95-9692-9e9676616af9 (TCGA-KM-A7QC.D3E87845-70EA-4641-BDCE-6961254E5108.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).